MMRF case MMRF_2489 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5d29ee5d-666c-4112-a8b4-de9f7bcd52ce

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.3 years (20,575 days); ISS stage: I; Days to last known disease status: 714 days (2.0 years); Days to last follow up: 714 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 73 days; Days to treatment end: 73 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 98 days; Days to treatment end: 98 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 99 days; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 273 days; Days to treatment end: 276 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 275 days; Days to treatment end: 275 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 277 days; Days to treatment end: 277 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 4.55 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 81.2 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.92 µg/mL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.65 mmol/L; Albumin 40 g/L; Total Protein 10.6 g/dL; Glucose 6.16 mmol/L.
- Day 92 (ECOG 0): M Protein 1.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.4 mg/dL; Immunoglobulin G 21.3 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 9.3 ×10⁹/L; Absolute Neutrophil 8 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 1.95 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 4.07 mmol/L.
- Day 193 (ECOG 0): M Protein 1.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.36 mg/dL; Immunoglobulin G 18.5 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.85 µg/mL; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 39.2 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 305 (ECOG 0): M Protein 0.72 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.36 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 21.1 ×10⁹/L; Absolute Neutrophil 16.7 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 1.98 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 6 mmol/L.
- Day 364 (ECOG 0): M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.43 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.1 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 6.6 mmol/L.
- Day 427 (ECOG 0): M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.94 mmol/L.
- Day 526 (ECOG 0): M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 6.71 mmol/L.
- Day 617 (ECOG 0): M Protein 0.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 11 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.61 mmol/L.
- Day 714 (ECOG 0): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.76 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.

Other clinical attributes
- Day 1: Weight: 79 kg; Height: 172 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2489_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2489_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
